Somatic mutation profile of tumor specimen MP2PRT-PANWYH-TMP1-A (aliquot MP2PRT-PANWYH-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANWYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,786 days).
Specimen MP2PRT-PANWYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9436e42-2ab8-4169-81fe-097afb65f1ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWYH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWYH-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10f294c6-67e3-4128-97e8-bfeb37b943c8

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Nonsense Mutation 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 76/256 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- C3 | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 151/365 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1421843172, COSV55577235; called by muse, mutect2, varscan2
- CUL7 | c.4058G>A p.S1353N | Missense Mutation (SNP) | VAF 149/366 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54820119; called by muse, mutect2, varscan2
- CYP2A13 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs200738334; called by muse, mutect2, varscan2
- FSCN2 | c.1314C>A p.S438R | Missense Mutation (SNP) | VAF 201/498 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs756328540; called by muse, mutect2, varscan2
- GPR158 | c.3085G>A p.V1029I | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs770315576; called by muse, mutect2, varscan2
- PRR5 | c.706C>T p.R236C (on ENST00000336985 / NM_181333.4; = p.R227C on NM_015366.4) | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as rs756128125, COSV50060201; called by muse, mutect2
- TRAV22 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs771830762; called by muse, mutect2, varscan2
- ETV6 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 22/237 reads (9%) | called by muse, mutect2
- FEM1A | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 222/608 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MYO15A | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 239/603 reads (40%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO1 | c.2974A>T p.I992F | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); called by mutect2, varscan2
- SLC7A11 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- TTBK1 | c.3583C>T p.Q1195* | Nonsense Mutation (SNP) | VAF 161/394 reads (41%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.1040G>A p.C347Y | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSWIM2 | c.1039T>A p.C347S | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP2 | c.2127C>A p.G709= | Silent (SNP) | VAF 116/351 reads (33%) | catalogued as rs762250248; called by muse, mutect2, varscan2
- ZNF732 | c.1341A>G p.K447= | Silent (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- COL6A5 | c.-181G>A | 5'UTR (SNP) | VAF 154/360 reads (43%) | called by muse, varscan2
- TAF1A | chr1:222590064 G>T | 5'Flank (SNP) | VAF 119/351 reads (34%) | called by muse, mutect2, varscan2
